Gene-level copy-number profile of tumor specimen ALCH-B0AN-TTP1-A from ALCHEMIST case ALCH-B0AN, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 71.2 years (26,004 days).
Specimen ALCH-B0AN-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ff0ba023-d698-40ef-be48-14ac004010ea.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B0AN-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,717 have no estimate.
https://portal.gdc.cancer.gov/files/96d60e9c-3f53-44d2-8e5d-4d6dc67fe78b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 146; copy number 1: 20,217; copy number 2: 33,580; copy number 3: 3,624; copy number 4: 570; copy number 5: 769.

Homozygous deletions (total copy number 0; autosomes only): 103 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:3,735,511–3,747,373, 2 genes (within-gene range 0–2): TP73-AS1, AL136528.1.
- chr1:11,654,375–11,674,354, 2 genes (within-gene range 0–1): FBXO44, FBXO6.
- chr1:12,567,910–12,618,210, 3 genes: DHRS3, RNU6ATAC18P, MIR6730.
- chr1:12,926,162–12,928,253, 1 gene (within-gene range 0–1): PRAMEF29P.
- chr1:13,222,705–13,421,328, 13 genes: PRAMEF18, PRAMEF31P, PRAMEF5, PRAMEF32P, RNU6-771P, PRAMEF8, PRAMEF33, PRAMEF15, AC243961.1, PRAMEF14, PRAMEF19, PRAMEF17, PRAMEF20.
- chr1:18,839,599–18,859,682, 1 gene (within-gene range 0–1): TAS1R2.
- chr2:90,159,840–90,160,335, 1 gene (within-gene range 0–1): IGKV1D-12.
- chr2:91,617,160–91,685,884, 3 genes (within-gene range 0–1): LSP1P4, RNA5SP100, DRD5P1.
- chr6:39,314,698–39,322,968, 1 gene: KCNK16.
- chr7:140,435,316–140,435,787, 1 gene: AC069335.1.
- chr8:47,189,305–47,202,897, 5 genes (within-gene range 0–1): AC120036.3, AC120036.4, ATP6V1G1P2, AC120036.2, IGLV8OR8-1.
- chr9:21,135,598–25,678,440, 69 genes (broad region; genes not listed).
- chr10:132,783,179–132,786,147, 1 gene (within-gene range 0–2): NKX6-2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 769 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–1,634,005, 60 genes, copy number 5: AC113430.1, PLEKHG4B, Y_RNA, LRRC14B, AC021087.4, CCDC127, AC021087.3, SDHA, AC021087.5, AC021087.1, PDCD6, PDCD6-AHRR, AC021087.2, AHRR, AC010442.1, AC010442.2, EXOC3-AS1, EXOC3, PP7080, SLC9A3, SLC9A3-AS1, AC106772.2, MIR4456, AC106772.1, CEP72, TPPP, AC026740.1, ZDHHC11B, BRD9P2, ZDHHC11, SPCS2P3, BRD9, TRIP13, AC122719.3, AC122719.1, AC122719.2, AC116351.1, AC116351.2, NKD2, SLC12A7, MIR4635, CTD-3080P12.3, SLC6A19, SLC6A18, AC114291.1, TERT, MIR4457, CLPTM1L, LINC01511, MTCO2P32, AC026748.3, SLC6A3, LPCAT1, MIR6075, AC091849.2, SDHAP3, AC026412.3, AC091849.1, AC026412.1, AC026412.2.
- chr5:6,448,859–45,895,970, 559 genes, copy number 5 (broad region; genes not listed).
- chr5:57,574,027–57,899,162, 3 genes, copy number 5: LINCR-0003, AC106822.1, LINC02225.
- chr5:58,969,038–60,522,120, 5 genes, copy number 5 (within-gene range 3–5): PDE4D, AC092343.1, AC008833.1, NDUFB4P2, MIR582.
- chr5:157,142,933–157,255,185, 1 gene, copy number 5 (within-gene range 4–5): ITK.
- chr5:157,199,242–160,345,396, 62 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr5:173,578,275–176,510,074, 63 genes, copy number 5 (broad region; genes not listed).
- chr15:85,380,571–85,749,358, 10 genes, copy number 5 (within-gene range 3–5): AKAP13, MIR7706, RNU7-79P, FABP5P9, AC087286.3, AC087286.2, AC087286.1, RNU6-1280P, AC087286.4, AC021739.3.
- chr15:92,805,770–93,027,996, 6 genes, copy number 5 (within-gene range 3–5): AC106028.2, AC106028.4, CHASERR, AC013394.1, CHD2, MIR3175.

Autosomal genes at a single copy (total copy number 1): 17,404. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
